Somatic mutation profile of tumor specimen TCGA-2Z-A9JD-01A (aliquot TCGA-2Z-A9JD-01A-11D-A42J-10) from TCGA case TCGA-2Z-A9JD, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.7 years (24,370 days).
Specimen TCGA-2Z-A9JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 110f7b22-afe7-440c-82a2-a154b97719f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JD-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JD-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbe81dbe-0d21-4a8d-882c-1704b8fd6b08

The open-access MAF lists 113 somatic variants for this specimen: 82 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 28, Frame Shift Del 12, Nonsense Mutation 3, Intron 2, In Frame Del 2, Frame Shift Ins 2, RNA 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.2123T>C p.V708A (on ENST00000404938 / NM_001163941.2; = p.V263A on NM_178559.6) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99328507; called by muse, mutect2, varscan2
- ACSS2 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.278); catalogued as COSV53623990; called by muse, mutect2, varscan2
- ADAM15 | c.621T>G p.D207E | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.997); catalogued as COSV99665027; called by muse, varscan2
- ALG14 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100930866; called by muse, mutect2, varscan2
- AQP12B | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV101315890; called by muse, mutect2, varscan2
- ARHGAP26 | c.702C>A p.N234K | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as COSV99191015; called by muse, mutect2, varscan2
- ATP1A3 | c.134C>G p.T45R (on ENST00000545399 / NM_001256214.2; = p.T32R on NM_152296.5) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV57490626; called by muse, mutect2, varscan2
- CACNA1D | c.530T>G p.F177C | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as rs1300567203, COSV99858360; called by muse, mutect2, varscan2
- CLCN1 | c.2404-1G>T p.X802_splice | Splice Site (SNP) | VAF 43/71 reads (61%) | catalogued as COSV100578104; called by muse, mutect2, varscan2
- COL19A1 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.812); catalogued as COSV100506413, COSV59590044; called by muse, mutect2, varscan2
- CRH | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99396215; called by muse, mutect2, varscan2
- DNAH3 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs200178510, COSV54533114; called by muse, mutect2, varscan2
- DNAJC5G | c.341G>C p.R114T | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV99940555; called by muse, mutect2, varscan2
- EEF1A1 | c.1285A>G p.M429V | Missense Mutation (SNP) | VAF 123/315 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs754096369, COSV100303325; called by muse, mutect2, varscan2
- EFNA1 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as COSV100310368; called by muse, mutect2, varscan2
- ELAPOR2 | c.882G>T p.K294N (on ENST00000450689 / NM_001142749.3; = p.K127N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as COSV51885756; called by muse, mutect2, varscan2
- ESRP1 | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV100619339; called by muse, mutect2, varscan2
- FANCA | c.3827A>C p.N1276T | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV99234994; called by muse, mutect2
- FAXDC2 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV100303815; called by muse, mutect2, varscan2
- FBLN5 | c.1285del p.I429Sfs*8 | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | catalogued as COSV99969739; called by mutect2, pindel, varscan2
- FLG2 | c.5855G>A p.G1952E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101165700, COSV66166369; called by muse, mutect2, varscan2
- GANC | c.2339C>A p.P780Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | PolyPhen probably damaging (0.99); catalogued as rs764337885, COSV100530941; called by muse, mutect2, varscan2
- GFM2 | c.2216A>G p.Y739C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99714407; called by muse, mutect2, varscan2
- GPT | c.1489T>C p.*497Rext*? | Nonstop Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99477618; called by muse, mutect2, varscan2
- GRIN2D | c.2445G>C p.E815D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV99474402; called by muse, mutect2, varscan2
- IDUA | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99926027; called by muse, mutect2, varscan2
- LATS1 | c.1972C>G p.L658V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV99486079; called by muse, mutect2, varscan2
- LRIG2 | c.2768A>G p.Y923C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs761558651, COSV100743412; called by muse, mutect2
- MAPKAPK2 | c.1103A>G p.E368G | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV99685958; called by muse, mutect2, varscan2
- MPRIP | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs754464266, COSV59053550; called by muse, mutect2, varscan2
- MTUS1 | c.183C>G p.D61E | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs1032472871, COSV100029483; called by muse, mutect2, varscan2
- MYH6 | c.3220G>A p.D1074N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs375169402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.5575G>T p.D1859Y | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101261594; called by muse, mutect2, varscan2
- N4BP2 | c.1870T>C p.S624P | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99788754; called by muse, mutect2, varscan2
- PCDHGB6 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV99539248; called by muse, mutect2, varscan2
- PDZD8 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780455053, COSV100559529; called by muse, mutect2, varscan2
- PGAP6 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as rs1283185470, COSV99170687; called by muse, mutect2, varscan2
- PGC | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100757011; called by muse, mutect2, varscan2
- PKHD1 | c.11003A>T p.D3668V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764471876, COSV100944335; called by muse, mutect2, varscan2
- PON1 | c.822T>A p.D274E | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV99732331; called by muse, mutect2, varscan2
- PPARGC1B | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV100494812; called by muse, mutect2, varscan2
- PPFIA1 | c.1259A>C p.E420A | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV99557494; called by muse, mutect2, varscan2
- PPP1R26 | c.3161G>C p.G1054A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.134); catalogued as rs902962211, COSV100778077, COSV63356508; called by muse, mutect2, varscan2
- PRKAG2 | c.593dup p.D199Gfs*74 | Frame Shift Ins (INS) | VAF 76/150 reads (51%) | catalogued as rs397517275; ClinVar: uncertain significance; called by mutect2, varscan2
- PRKDC | c.394A>T p.I132F | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100040863; called by muse, mutect2, varscan2
- PTK2 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.169); catalogued as COSV100570333; called by muse, mutect2, varscan2
- RBPJL | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100643508; called by muse, mutect2
- RESF1 | c.1010T>A p.F337Y | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100440375; called by muse, mutect2, varscan2
- RHOT2 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99553492; called by muse, mutect2, varscan2
- RIPK4 | c.1220A>G p.E407G (on ENST00000352483; = p.E359G on NM_020639.3) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.99); catalogued as COSV100205004; called by muse, mutect2, varscan2
- RTN3 | c.1872A>T p.E624D (on ENST00000377819 / NM_001265589.2; = p.E605D on NM_201428.3) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV100380198; called by muse, mutect2, varscan2
- SEC16A | c.2533T>C p.F845L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV99258582; called by muse, mutect2, varscan2
- SECISBP2L | c.2846A>G p.D949G (on ENST00000559471 / NM_001193489.2; = p.D904G on NM_014701.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769635839, COSV99960418; called by mutect2, varscan2
- SFXN4 | c.358A>T p.T120S | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV100341103; called by muse, mutect2, varscan2
- SGK1 | c.362_364del p.E121del | In Frame Del (DEL) | VAF 31/106 reads (29%) | catalogued as rs776473640; called by pindel, varscan2
- SIPA1L1 | c.4931T>C p.F1644S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100665611; called by muse, mutect2, varscan2
- SLITRK4 | c.699T>G p.Y233* | Nonsense Mutation (SNP) | VAF 76/98 reads (78%) | catalogued as COSV100567369; called by muse, mutect2, varscan2
- SMARCA2 | c.3457G>C p.D1153H | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD154685, COSV100571146; called by muse, mutect2, varscan2
- SNAI2 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99194962, COSV99194972; called by muse, mutect2, varscan2
- SPAG7 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99236554; called by muse, mutect2, varscan2
- SZT2 | c.7771T>C p.C2591R (on ENST00000634258 / NM_001365999.1; = p.C2534R on NM_015284.4) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100987346; called by muse, mutect2, varscan2
- TJP2 | c.2520T>G p.F840L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs748208246, COSV99601198; called by muse, mutect2, varscan2
- TLN1 | c.5339A>G p.K1780R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.751); catalogued as COSV59210531; called by muse, mutect2, varscan2
- TTN | c.95833G>T p.E31945* (on ENST00000591111; = p.E24521* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100615604, COSV60026973; called by muse, mutect2
- ZBTB32 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1454371024, COSV99386082; called by muse, mutect2, varscan2
- ZFAT | c.3392T>C p.I1131T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1431450036, COSV100914637; called by muse, mutect2, varscan2
- ZFHX3 | c.3830T>C p.V1277A | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99212890; called by muse, varscan2
- ZNF141 | c.639A>G p.I213M | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV99549738; called by muse, mutect2, varscan2
- ZNF214 | c.118A>T p.M40L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99547432; called by muse, mutect2, varscan2
- AMT | c.241del p.V81Cfs*15 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, varscan2
- BAP1 | c.1509del p.F503Lfs*68 | Frame Shift Del (DEL) | VAF 32/62 reads (52%) | called by pindel, varscan2
- EP400 | c.4665del p.S1556Rfs*12 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- IQCD | c.32del p.L11Cfs*10 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel
- KCNIP3 | c.711_721del p.A238Gfs*2 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- KNL1 | c.3600dup p.D1201* (on ENST00000346991 / NM_170589.5; = p.D1175* on NM_144508.5) | Frame Shift Ins (INS) | VAF 27/98 reads (28%) | called by mutect2, pindel, varscan2
- LDB3 | c.419_420del p.P140Hfs*3 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | called by mutect2, pindel, varscan2
- MSH2 | c.636del p.K212Nfs*2 | Frame Shift Del (DEL) | VAF 39/113 reads (35%) | called by mutect2, pindel, varscan2
- NUGGC | c.5_7del p.A2del | In Frame Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- RERE | c.1344_1356del p.A449Tfs*33 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- SSTR1 | c.208del p.L70Wfs*13 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- SWI5 | c.166del p.L56Sfs*46 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- WDR81 | c.3821del p.P1274Rfs*2 (on ENST00000409644 / NM_001163809.2; = p.P223Rfs*2 on NM_152348.4) | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- ABL1 | c.1035T>C p.T345= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100584061; called by muse, mutect2, varscan2
- ACADSB | c.135A>C p.T45= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100715209; called by muse, mutect2, varscan2
- ADGRL1 | c.342C>T p.P114= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as rs149098258; called by muse, mutect2, varscan2
- ARID5B | c.1897C>T p.L633= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV99689763; called by muse, mutect2, varscan2
- ATP5F1C | c.621T>C p.N207= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100184336; called by muse, mutect2, varscan2
- CCDC39 | c.2616A>G p.T872= | Silent (SNP) | VAF 65/96 reads (68%) | catalogued as COSV99869112; called by muse, mutect2, varscan2
- CDADC1 | c.1104T>A p.A368= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV99212566; called by muse, mutect2, varscan2
- CLDN7 | c.400T>C p.L134= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV100598153; called by muse, mutect2, varscan2
- COQ6 | c.438T>C p.D146= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs756378186, COSV99473952; called by muse, mutect2, varscan2
- DEF8 | c.312C>A p.A104= (on ENST00000268676 / NM_207514.3; = p.A43= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99240518; called by muse, mutect2, varscan2
- DENND1A | c.2811G>A p.K937= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV101012020; called by muse, mutect2, varscan2
- DOCK2 | c.1215C>A p.T405= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV99912821; called by muse, varscan2
- E2F4 | c.303G>A p.K101= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100103940; called by muse, mutect2, varscan2
- FDPS | c.129C>T p.A43= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100756216; called by muse, mutect2, varscan2
- GREB1 | c.3486G>A p.Q1162= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as rs1240188111, COSV99303002; called by muse, mutect2, varscan2
- IL6ST | c.1773A>G p.R591= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100410860; called by muse, mutect2, varscan2
- INO80 | c.3063A>G p.P1021= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV100731847; called by muse, mutect2, varscan2
- MAF | c.1107C>A p.P369= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100391621; called by muse, mutect2
- MTERF2 | c.270T>C p.D90= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1245655680, COSV99526799; called by muse, mutect2
- PLAAT3 | c.399C>T p.V133= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100071777; called by muse, mutect2, varscan2
- RRP8 | c.72T>A p.P24= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV99601925; called by muse, mutect2, varscan2
- SAC3D1 | c.837C>T p.V279= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100101109; called by muse, mutect2, varscan2
- SHROOM3 | c.1155T>C p.P385= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV56023935; called by muse, mutect2, varscan2
- SIPA1L3 | c.4623G>C p.R1541= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99728981; called by muse, mutect2, varscan2
- TMEM139 | c.538T>C p.L180= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV100131022; called by muse, mutect2, varscan2
- TMEM245 | c.1161C>T p.L387= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV101002348; called by muse, mutect2, varscan2
- TSHZ1 | c.2253C>A p.S751= (on ENST00000580243 / NM_001308210.2; = p.S706= on NM_005786.6) | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs760818403, COSV100433728; called by muse, mutect2, varscan2
- ZMYM6 | c.3477A>G p.Q1159= | Silent (SNP) | VAF 85/251 reads (34%) | catalogued as COSV100593197; called by muse, mutect2, varscan2
- AMACR | c.739+1134C>A | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100163049; called by muse, mutect2, varscan2
- MIR30A | n.60_65dup | RNA (INS) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- SLC28A1 | c.461+302A>G | Intron (SNP) | VAF 52/115 reads (45%) | catalogued as COSV99723005; called by muse, mutect2, varscan2
